TCGA case TCGA-AN-A0AL — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3e9f93c0-aa79-4b4c-bd6c-b3325912362a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 41.9 years (15,286 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Lower Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 5; Micrometastasis present: No.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 198 days; Disease response: Tumor Free.
- Days to follow up: 227 days; Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 0; Test value range: <10%.
- ESR1 (IHC): Negative; Staining intensity value: 0; Test value range: <10%.
- PGR (IHC): Negative; Staining intensity value: 0; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AN-A0AL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 300 mg.
  Slide TCGA-AN-A0AL-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 25.
  Slide TCGA-AN-A0AL-01A-01-BSA: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 5.
- Sample TCGA-AN-A0AL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AN-A0AL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Er positivity method: dextran coated charcoal; Pr positivity define method: dextran coated charcoal; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: No; Er IHC score: 0; Her2 IHC score: 0; Method initial path diagnosis: Tumor resection; Her2 IHC percent positive: <10%; Her2 positivity method text: dextran coated charcoal; Prospective collection: No; Retrospective collection: Yes; Er status IHC Percent Positive: <10%; Pr status IHC percent positive: <10%; Pr positivity IHC intensity score: 0.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Lower Outer Quadrant.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 227 days; disease-specific survival: no event (censored), 227 days; disease-free interval: no event (censored), 227 days; progression-free interval: no event (censored), 227 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AN-A0AL-01A-11D-A011-01): tumor purity 0.78, ploidy 1.92, whole-genome doublings 0.
